Gene-level copy-number profile of tumor specimen TCGA-61-2009-01A from TCGA case TCGA-61-2009, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.1 years (23,772 days).
Specimen TCGA-61-2009-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0e1c9ec4-1b65-4dd9-ab99-2abc8fdea3ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2009-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3d948912-98bd-44cf-b8f2-cb13bdf44d6d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,943; copy number 2: 10,000; copy number 3: 21,506; copy number 4: 10,424; copy number 5: 7,965; copy number 6: 4,921; copy number 7: 1,150; copy number 8: 923; copy number 10: 68; copy number 11: 784; copy number 13: 66; copy number 15: 23; copy number 19: 10; copy number 21: 11; copy number 26: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2009-01A-01D-0663-01): tumor purity 0.57, ploidy 3.58, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,061 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,862,175–241,357,230, 52 genes, copy number 7 (within-gene range 6–7): AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr3:128,153,481–128,408,646, 1 gene, copy number 8 (within-gene range 3–8): EEFSEC.
- chr3:128,462,439–198,222,513, 1,248 genes, copy number 8–11 (broad region; genes not listed).
- chr6:44,809,317–45,377,953, 1 gene, copy number 7 (within-gene range 6–7): SUPT3H.
- chr6:45,097,496–51,623,428, 85 genes, copy number 7 (broad region; genes not listed).
- chr11:29,159,956–33,357,023, 67 genes, copy number 13–15 (within-gene range 13–17) (broad region; genes not listed).
- chr11:34,404,663–35,020,591, 12 genes, copy number 7: AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343.
- chr14:20,365,667–21,116,703, 58 genes, copy number 13–26 (within-gene range 4–26): TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1, PNP, AL355075.3, RNASE10, PTCD2P1, SETP1, RNASE9, AL163195.3, RNASE11, AL163195.2, RNASE12, AL163195.1, OR6S1, Y_RNA, ANG, RNASE4, AL163636.1, EGILA, RANBP20P, EDDM3DP, EDDM3A, EDDM3B, RNASE6, AL133371.2, RNASE1, AL133371.3, AL133371.1, RNASE3, AL355922.4, AL355922.3, AL355922.1, RNASE2, RN7SL189P, AL355922.2, METTL17, AL161668.3, SLC39A2, NDRG2, MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13, RNASE7, RNASE8, ARHGEF40, ZNF219, TMEM253, AL161668.1, CKAP2P1, RNU6-252P.
- chr14:21,209,136–22,190,713, 75 genes, copy number 10–21 (within-gene range 4–21) (broad region; genes not listed).
- chr14:22,202,583–22,227,254, 4 genes, copy number 10: TRAV26-2, TRAV34, TRAV35, TRAV36DV7.
- chr20:87,250–64,313,132, 1,458 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 37. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
